Surgical pathology report (de-identified scan), TCGA case TCGA-MG-AAMC, project TCGA-PRAD (Prostate Adenocarcinoma), tissue source site BLN - Baylor, specimen TCGA-MG-AAMC-01A (Primary Tumor).

[page 1 of 2]
----- SURGICAL PATHOLOGY -----

MEDICAL RECORD |

SURGICAL PATHOLOGY

PATHOLOGY REPORT

Laboratory:

Accession No.

Submitted by:

Date obtained:

Specimen (Received

A. PERI-PROSTATIC LYMPH NODE

B. PROSTATE GLAND WITH BILATERAL PELVIC LYMPH NODES

BRIEF CLINICAL HISTORY:

PREOPERATIVE DIAGNOSIS:

prostate cancer

OPERATIVE FINDINGS:

POSTOPERATIVE DIAGNOSIS:

prostate cancer

Surgeon/physician:

PATHOLOGY REPORT

Laboratory:

Accession No.

GROSS DESCRIPTION:

A. The specimen consists of a 3.2 x 3.0 x 0.8 cm aggregate of golden-yellow, lobulated adipose tissue which is sectioned and palpated to reveal no obvious lymphoid tissue. The specimen is submitted in toto in cassettes A1-A3.

B. The specimen consists of a 48.2 g (5.2 cm from medial to lateral x 4.5 cm from anterior to posterior x 3.5 cm from apex to base) radical prostatectomy specimen. The specimen has a trimmed weight of 36.0 g. The external surface of the specimen is tan to pink and irregular. The right half of the specimen is inked black, and the left half of the specimen is inked blue.

The specimen is serially sectioned from apex to base to reveal multiple tan to yellow, ill-defined nodules, ranging in size from 0.3 to 0.7 cm in greatest dimension, which are appreciated throughout the specimen.

The remainder of the cut surface is tan-white and smooth, with no discrete lesions. Also received within the same container is a 5.0 x 3.4 x 0.5 cm aggregate of golden-yellow, lobulated adipose tissue, which is sectioned and palpated to reveal four possible whole lymph nodes, ranging in size from 0.5 to 1.5 cm in greatest dimension.

The specimen is submitted as follows: B1- apical margin; B2- basal margin; B3-B30- prostate, in its entirety sequentially submitted from apex to base; B31- base of bilateral seminal vesicles and vasa deferentia where they enter the prostate gland at the base; B32- distal bilateral vasa deferentia and seminal vesicles; B33-B38- separately included adipose tissue and possible whole lymph nodes, entirely submitted.

MICROSCOPIC EXAM

DIAGNOSIS:

- A. Soft tissue, periprostatic, excision:
- ADIPOSE TISSUE
- NO LYMPH NODES IDENTIFIED
- NO EVIDENCE OF MALIGNANCY

ICD-O-3

Adenocarcinoma NOS 8140/3

Site: Prostate NOS C61.9

9/27/14

[page 2 of 2]
- B. Prostate and seminal vesicles, radical prostatectomy and bilateral pelvic lymph node dissection:
- ADENOCARCINOMA OF PROSTATE

PROCEDURE: Radical prostatectomy
PROSTATE SIZE: Weight: 36.0 grams, Size: 5.2 x 4.5 x 3.5 cm
LYMPH NODE SAMPLING: Pelvic lymph node dissection
HISTOLOGIC TYPE: Adenocarcinoma
HISTOLOGIC GRADE: Gleason: 4+5=9 A Tertiary pattern of Gleason pattern 3 is also noted
TUMOR QUANTITATION: Tumor involves 15% of prostate
EXTRAPROSTATIC EXTENSION: Present, established
SEMINAL VESICLE INVASION: Not identified
MARGINS: Margins uninvolved by invasive carcinoma
TREATMENT EFFECT ON CARCINOMA: Not identified
LYMPH-VASCULAR INVASION: Not identified
PERINEURAL INVASION: Present
PATHOLOGICAL STAGING:
Primary Tumor: pT3a
Regional lymph nodes: pN0
- Number examined: 8
- Number involved: 0
Distant Metastasis: Not applicable
ADDITIONAL PATHOLOGICAL FINDINGS:
High-grade prostatic intraepithelial neoplasia

Staff pathologist
Signed

(End of report)

Reviewed (Initials)	Paul	Date Reviewed: 12/24/13

Source: NCI Genomic Data Commons file 7a1110bf-56cc-4e9d-a713-66d4f3e7d665 (TCGA-MG-AAMC.CBC765C1-9191-4A40-979F-CF2434B10CAB.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).